CPTAC case C3L-04539 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2a389115-1c85-46bf-be0f-72928ef33796

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1942; Vital status: Dead; Days to death: 409 days (1.1 years); Year of death: 2019; Cause of death: Cancer Related.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Temporal lobe; Age at diagnosis: 75.8 years (27,684 days); Year of diagnosis: 2018; Days to last known disease status: 409 days (1.1 years); Days to last follow up: 282 days.
   Pathology details: Greatest tumor dimension: 2.5 cm.

Follow-up (1 entry)
- Days to follow up: 282 days; Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 71.1 kg; Height: 177.8 cm; BMI: 22.49.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-04539-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 200 mg; Time between excision and freezing: 15 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-04539-21: Section location: Temporal Lobe; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3L-04539-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
